Surgical pathology report (de-identified scan), TCGA case TCGA-BA-7269, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-7269-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

Case Number : [REDACTED]

Diagnosis:

A: Tongue, medial margin, biopsy

- Fragment of squamous mucosa with underlying muscle and salivary gland.
- No evidence of malignancy.

B: Tongue, posterior base margin, biopsy

- Fragment of muscle with salivary gland with chronic inflammation.
- No evidence of malignancy.

C: Tongue, lateral deep margin, biopsy

- Fragment of muscle with mild chronic inflammation.
- No evidence of malignancy.

D: Tongue, lateral mucosal margin, biopsy

- Fragment of squamous mucosa with underlying fibroadipose tissue and muscle with acute and chronic inflammation.
- No evidence of malignancy.

E: Tongue, anterior margin, biopsy

- Fragment of squamous mucosa with underlying fibroadipose tissue and muscle with acute and chronic inflammation.
- No evidence of malignancy.

F: Tongue, right posterior, partial glossectomy

Tumor histologic type/subtype: squamous cell carcinoma, well differentiated

Primary site: tongue

Size: 2.1 cm

Extent of invasion:

Angiolymphatic invasion: not identified

Perineural Invasion: positive (F1)

Bone invasion: n/a

Carcinoma in situ: Not identified

Surgical Margins: free of tumor

[page 2 of 5]
Lymph nodes: none submitted

Other significant findings: None

AJCC PATHOLOGIC TNM STAGE: pT2 pN1

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

G: Lymph nodes, right neck, Level 1, excision

- No evidence of malignancy in six lymph nodes (0/6).

H: Lymph nodes, right neck, Level 2, excision

- Metastatic squamous cell carcinoma identified in one of three lymph nodes (1/3).

- Size of metastasis 1.1 cm, no extranodal extension of tumor identified.

I: Lymph nodes, right neck, Level 3, excision

- No evidence of malignancy in eight lymph nodes (0/8).

Intraoperative Consult Diagnosis:

sultation was requested by Dr. in OR # [REDACTED] at [REDACTED]

FSA1: Medial tongue margin, removal

- No tumor seen

FSB1: Posterior tongue base margin, removal

- No tumor seen

FSC1: Lateral deep tongue margin, removal

- No tumor seen

FSD1: Lateral mucosal margin, removal

- No tumor seen

FSE1: Anterior tongue margin, removal

- No tumor seen

Drs. and [REDACTED]

Frozen Section Pathologist:, MD

[page 3 of 5]
inical History:

-year-old male with tongue cancer. A right hemiglossectomy was performed.

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "medial tongue margin." The specimen is a 1.5 x 0.7 x 0.6 cm red/tan soft tissue fragment that is entirely submitted in block FSA1,

Container B is additionally labeled "posterior tongue base margin." The specimen is a 1.2 x 0.5 x 0.5 cm red/tan soft tissue fragment that is entirely submitted in block FSB1,

Container C is additionally labeled "lateral deep tongue margin." The specimen is a 1 x 0.3 x 0.3 cm red/tan soft tissue fragment that is entirely submitted in block FSC1,

Container D is additionally labeled "lateral mucosal margin." The specimen is a 1.3 x 0.3 x 0.3 cm red/tan soft tissue fragment that is entirely submitted in block FSD1,

Container E is additionally labeled "anterior tongue margin." The specimen is a 1.2 x 0.3 x 0.3 cm red/tan soft tissue fragment that is entirely submitted in block FSE1,

Container F is additionally labeled "right posterior tongue."

Specimen fixation: formalin

Type of specimen: partial glossectomy

Size of specimen: The specimen measures 3.4 cm anterior/posterior, 4.1 cm medial/lateral, and 3.0 cm superior/inferior.

Laterality:

Orientation of specimen: By sutures: short suture=anterior, long suture=medial

Inking: anterior=red, posterior=yellow, medial=blue, lateral=green and deep=black

Tumor description: The mass is an ulcerative, hemorrhagic lesion that measures 1.2 x 0.7 cm and extends to a depth of 0.3 cm. It

[page 4 of 5]
has a vaguely nodular surface and does appear to invade into the underlying muscle.

Location of tumor: Along the lateral aspect of the specimen and, therefore, the lateral aspect of the tongue towards the posterior aspect.

Tumor size: 2.1 x 1.7 x 1.5 cm

Extent of tumor: Tumor appears to invade into the underlying lingual musculature to approximately 1.5 cm.

Presence/absence of bone involvement: absent

Distance of tumor to surgical margins: The mass measures 0.6 cm to posterior, 1.3 cm to anterior, 1.2 cm to medial, 0.8 cm to lateral, and approximately 1.0 cm to deep.

Description of remainder of tissue: The remaining tissue consists of pink/tan, nodular lingual mucosa with papillae, that segues into pink/tan, smooth oral mucosa. The underlying musculature is otherwise unremarkable.

Tissue submitted for special investigations: yes; Tumor to Tissue Procurement

Lymph nodes: not assessed

Digital photograph taken: no

Block summary:

F1 - representative cross section of mass
F2 - mass to medial- posterior margin
F3 - mass to anterior margin
F4 - mass to posterior margin
F5 - additional mass to lateral/deep margin

Container G is additionally labeled "right neck, Level 1A." The specimen consists of two fragments of yellow/tan fibroadipose tissue that measures 2.8 x 2.3 x 1.1 cm. Eight lymph node candidates are identified within the fibroadipose tissue and range in size from 0.3 up to 1.0 cm in greatest dimension.

[page 5 of 5]
Block summary:

- G1 - five lymph node candidates
- G2 - two lymph node candidates, bisected node inked green
- G3 - one lymph node candidate, bisected

Container H is additionally labeled "right neck, Level 2." The specimen consists of a single fragment of yellow/tan fibroadipose tissue that measures 3.5 x 2.5 x 1.4 cm in aggregate. Within fibroadipose tissue, five lymph node candidates are identified that range in size from 0.5 up to 3.5 cm in greatest dimension.

Block summary:

- H1 - two lymph node candidates
- H2 - one lymph node candidate, bisected
- H3 - one lymph node candidate, bisected
- H4-H6 - largest lymph node candidate, sectioned

Container I is additionally labeled "right neck, Level 3." The specimen consists of a single fragment of yellow/tan fibroadipose tissue that measures 3.5 x 1.8 x 1.1 cm. Ten lymph node candidates are identified within the fibroadipose tissue and ranges in size from 0.3 up to 1.2 cm in greatest dimension.

Block summary:

- I1 - five lymph node candidates
- I2 - three lymph node candidates
- I3 - one lymph node candidate, bisected
- I4 - one lymph node candidate, bisected

Source: NCI Genomic Data Commons file 89e21306-ea05-4d64-8ca0-46e75bf16bd0 (TCGA-BA-7269.AC8BA90F-D35D-45E2-9A89-FCDB5896720F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).